Somatic mutation profile of tumor specimen MBCProject_0044_T1_WES (aliquot MBCProject_0044_T1_WES_1) from CMI case MBCProject_0044, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 38.5 years (14,065 days).
Specimen MBCProject_0044_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8606866b-5a62-45ac-97c6-fed7f8b4b25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0044_SALIVA (Saliva), aliquot MBCProject_0044_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b16e1ae-e7f4-4b75-8e78-03782184d243

The open-access MAF lists 41 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 4, 3'UTR 2, Splice Site 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC025165.3 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1409991964; called by muse, varscan2
- APC | c.5669C>T p.S1890L | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV57337318, COSV57380267; called by muse, varscan2
- APC | c.5705C>T p.S1902F | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1554086917; ClinVar: uncertain significance; called by muse, varscan2
- C2orf42 | c.883T>G p.C295G | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs770958209; called by muse, mutect2, varscan2
- CAPN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1383039960, COSV54334980; called by muse, mutect2, varscan2
- CLCA4 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55366431; called by muse, mutect2
- MED13 | c.4217C>T p.P1406L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1397964632, COSV67266551; called by muse, mutect2
- SMAD4 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61690542; called by mutect2, varscan2
- ZFHX3 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99195641; called by muse, mutect2, varscan2
- ABCC4 | c.1372_1375del p.V458Sfs*31 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- APC | c.5704T>C p.S1902P | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, varscan2
- DPY19L1 | c.1295dup p.V433Cfs*4 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4455G>C p.Q1485H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LATS1 | c.2873C>A p.T958K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MDN1 | c.7218+1G>C p.X2406_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- NID1 | c.3553G>T p.D1185Y | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH15 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTPRF | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PUS7L | c.756G>C p.K252N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- RNASE11 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A9 | c.1799G>T p.S600I | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SPIN4 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.81); called by muse, mutect2
- TUBGCP6 | c.3856G>C p.A1286P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ANKS1A | c.1530C>T p.C510= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs369143066; called by muse, mutect2, varscan2
- ENPP2 | c.1890C>G p.L630= (on ENST00000075322 / NM_001040092.3; = p.L682= on NM_006209.5) | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs759438853; called by muse, mutect2, varscan2
- GAS2L1 | c.1293C>T p.A431= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- MR1 | c.51G>A p.V17= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- PTPRK | c.1563C>A p.I521= | Silent (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- QSER1 | c.4401T>G p.T1467= (on ENST00000399302; = p.T1596= on NM_001076786.3) | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV67899545; called by muse, mutect2
- RBMXL3 | c.1863C>T p.S621= | Silent (SNP) | VAF 60/257 reads (23%) | catalogued as rs1055448483; called by muse, mutect2, varscan2
- RICTOR | c.465T>A p.T155= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- TENM2 | c.1044G>A p.P348= (on ENST00000518659 / NM_001122679.2; = p.P157= on NM_001080428.3) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs146310303; called by muse, mutect2, varscan2
- AL353753.1 | n.363G>T | RNA (SNP) | VAF 4/42 reads (10%) | catalogued as rs1181533655; called by mutect2, varscan2
- C3orf33 | c.115-1546A>G | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as rs1189235651; called by muse, varscan2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 4/54 reads (7%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2
- MMAB | c.*1726A>T | 3'UTR (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2
- NGRN | chr15:90275528 G>A | 3'Flank (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- NOS3 | c.2985-562C>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- SLC11A2 | c.*1855A>G | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs1416142237; called by muse, varscan2
- UGP2 | c.255+4928C>A | Intron (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
